Somatic mutation profile of tumor specimen TCGA-X9-A971-01A (aliquot TCGA-X9-A971-01A-11D-A387-09) from TCGA case TCGA-X9-A971, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 52.6 years (19,207 days).
Specimen TCGA-X9-A971-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71ef31c2-069d-4851-91f0-c1d406ad9050.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X9-A971-10A (Blood Derived Normal), aliquot TCGA-X9-A971-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d789487-deec-47f7-a724-444b05c16daf

The open-access MAF lists 44 somatic variants for this specimen: 37 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 34, Silent 7, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2138A>T p.D713V | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99273504; called by muse, mutect2, varscan2
- ADAMTS20 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV67131691; called by muse, mutect2
- AL592490.1 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs1313291049, COSV69426707; called by muse, mutect2, varscan2
- ANXA8L1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1186334006; called by muse, mutect2
- CENPC | c.2821A>T p.I941L | Missense Mutation (SNP) | VAF 109/167 reads (65%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV99894176; called by muse, mutect2, varscan2
- DCSTAMP | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760724223, COSV52576948, COSV99886396, COSV99886886; called by muse, mutect2, varscan2
- EDEM1 | c.1939A>G p.M647V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1317506578, COSV99849319; called by muse, mutect2, varscan2
- EPHB6 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs765196557, COSV101235985; called by muse, mutect2, varscan2
- EXOC3L4 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV101197676; called by muse, mutect2
- FAM81B | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.059); catalogued as COSV99353019, COSV99353197; called by muse, mutect2, varscan2
- FN1 | c.5296A>G p.K1766E | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs755018889, COSV100117603; called by muse, mutect2, varscan2
- GABRD | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as rs901937998, COSV101059546, COSV101059558; called by muse, mutect2, varscan2
- GRP | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99901031; called by muse, mutect2, varscan2
- HAS2 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100392040; called by muse, mutect2, varscan2
- HDC | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs773972874, COSV51072354, COSV99983792; called by muse, mutect2, varscan2
- KCNA1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66838558; called by muse, mutect2, varscan2
- KDM4B | c.722A>C p.H241P | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346843; called by muse, mutect2, varscan2
- MROH7 | c.1848C>G p.I616M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1196095761, COSV100273746; called by muse, mutect2, varscan2
- MTMR7 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs748679120, COSV51670518; called by muse, mutect2, varscan2
- MYH11 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV55562487; called by muse, mutect2, varscan2
- NOTCH3 | c.5000G>C p.R1667P | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752437137, COSV54630605, COSV99658027; called by muse, mutect2, varscan2
- PARP2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99163000; called by muse, mutect2, varscan2
- PCNT | c.8656G>C p.E2886Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.601); catalogued as COSV100855717; called by muse, mutect2
- RAD51AP2 | c.2960T>A p.L987H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101208381; called by muse, mutect2, varscan2
- SLC25A2 | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV99508299; called by mutect2, varscan2
- SMC1B | c.3472C>G p.L1158V | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100663362; called by muse, mutect2
- SRGAP3 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs778822534, COSV100841128; called by muse, mutect2, varscan2
- STEAP2 | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.03); catalogued as COSV99840520; called by muse, mutect2, varscan2
- SYCP2 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100698354; called by muse, mutect2
- SYCP2 | c.81A>T p.K27N | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100698355; called by muse, mutect2, varscan2
- TARS2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs367984492, COSV100946011; called by muse, mutect2, varscan2
- TNC | c.5125+1G>C p.X1709_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as rs111797890, COSV100406020; called by muse, mutect2, varscan2
- UBXN10 | c.653C>A p.T218K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100907823; called by muse, varscan2
- ZNF490 | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV100267433; called by muse, mutect2
- ZNF536 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs749973474, COSV62823845; called by muse, mutect2, varscan2
- ZSWIM5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100655661; called by muse, mutect2, varscan2
- LRRK2 | c.5095del p.Y1699Ifs*10 | Frame Shift Del (DEL) | VAF 32/61 reads (52%) | called by mutect2, pindel*, varscan2
- ANKLE2 | c.1482G>T p.L494= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV100514240; called by muse, mutect2, varscan2
- CACNA1D | c.3534C>T p.Y1178= (on ENST00000350061 / NM_001128840.3; = p.Y1198= on NM_000720.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs148248303; called by muse, mutect2, varscan2
- CALML6 | c.432C>T p.N144= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs375295754; called by muse, mutect2, varscan2
- CRACD | c.3639C>A p.A1213= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV99949619; called by muse, mutect2, varscan2
- FGD5 | c.2517C>T p.D839= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs375849564, COSV99548746; called by muse, mutect2, varscan2
- PCDH17 | c.3126G>A p.A1042= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs534412507, COSV100931621, COSV100931767, COSV64975173; called by mutect2, varscan2
- PTPRF | c.3381G>A p.S1127= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs764478024, COSV100741038; called by muse, mutect2, varscan2
